Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0XV, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0XV-01A (Primary Tumor).

TSS Patient ID: .

Case #: DOB: Sex: **Female** Ethnicity (Race): .

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **Infiltrative ductal carcinoma**

Date of Procurement: I Anatomic Site: **Right Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **OCT**

Container: **block** Type of Procurement: **surgery** Grade: **2**

T Stage: **2** N Stage: **1** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

1CD-0-3

carcinoma, infiltrating duct, NOS 8500/3

*Site: breast, NOS 850.9 hw
10/21/11*

Source: NCI Genomic Data Commons file 8b5ca040-9eb5-4b88-835d-dac9497aae3d (TCGA-AN-A0XV.5F626AB6-EEB5-4005-97C5-9E48D9FA7730.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).